Somatic mutation profile of tumor specimen C3N-02972-01 (aliquot CPT0159220011) from CPTAC case C3N-02972, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 74.8 years (27,311 days).
Specimen C3N-02972-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61b22f85-52f0-470a-836f-230edd8c5103.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02972-31 (Blood Derived Normal), aliquot CPT0159480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65902d06-b010-4808-ade2-b3d462194234

The open-access MAF lists 104 somatic variants for this specimen: 65 protein-altering or splice-affecting, 24 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 24, Frame Shift Del 6, Nonsense Mutation 6, RNA 5, Intron 4, 5'UTR 3, 3'UTR 2, In Frame Del 1, 5'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 33/252 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.202T>C p.Y68H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs398123317, CM061927, CM131940, CM981667, COSV64289561, COSV64292590; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 97/271 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs121909238, CM051214, COSV100910602, COSV64296545, COSV64296755; ClinVar: pathogenic; called by muse, varscan2
- PTEN | c.389del p.R130Qfs*4 | Frame Shift Del (DEL) | VAF 106/375 reads (28%) | catalogued as rs121913292, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic; called by pindel, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 77/546 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD17A | c.658G>A p.V220I (on ENST00000292577 / NM_001130111.2; = p.V271I on NM_031213.4) | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as rs377143982; called by muse, mutect2, varscan2
- ARID1A | c.671del p.P224Rfs*8 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs1462224784; called by mutect2, pindel, varscan2
- ATP6V0D1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs529258503, COSV52098536; called by muse, mutect2, varscan2
- BLVRB | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.184); catalogued as rs148832924; called by muse, mutect2, varscan2
- CCL3L3 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 127/530 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1473476410; called by muse, mutect2, varscan2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2
- COL6A3 | c.8231C>T p.T2744M | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373680762; called by muse, mutect2
- DDX10 | c.1241A>C p.E414A | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1340761618; called by muse, mutect2, varscan2
- EDA2R | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs779459293; called by muse, mutect2, varscan2
- ELAPOR1 | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 27/252 reads (11%) | catalogued as rs1177973060, COSV64041434; called by muse, mutect2, varscan2
- FBXW5 | c.558C>G p.N186K | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs745710703; called by muse, mutect2, varscan2
- FYB2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs113615783; called by muse, mutect2
- GAA | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs777372252; called by muse, mutect2, varscan2
- HDAC10 | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1262339510; called by muse, mutect2, varscan2
- HDAC7 | c.1916G>T p.R639L (on ENST00000427332; = p.R678L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs781286336, COSV50381437; called by muse, mutect2, varscan2
- HSPG2 | c.5615C>T p.P1872L | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746717616, COSV65971652; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFI35 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs376682517; called by muse, mutect2, varscan2
- IP6K2 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 27/361 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.063); catalogued as rs200712199, COSV53662816; called by muse, mutect2
- ITPR3 | c.4364G>A p.R1455H | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.742); catalogued as rs376683742; called by muse, mutect2, varscan2
- MYO1G | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777006572, COSV51856560; called by muse, mutect2, varscan2
- MYO7B | c.5156C>A p.T1719K | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67348017; called by muse, mutect2, varscan2
- PIK3CA | c.224A>C p.Q75P | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV55911410; called by muse, mutect2
- PTEN | c.375A>T p.K125N | Missense Mutation (SNP) | VAF 60/368 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64290363, COSV64300471, COSV64309582; called by muse, varscan2
- RYR1 | c.7036G>A p.V2346M | Missense Mutation (SNP) | VAF 29/302 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs193922799, CM043566, COSV62102343; ClinVar: not provided; called by muse, mutect2
- SAE1 | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770367842; called by muse, varscan2
- SPATA31D1 | c.1765C>T p.R589* | Nonsense Mutation (SNP) | VAF 33/406 reads (8%) | catalogued as rs868142759; called by muse, mutect2
- WWC3 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1161736968, COSV101081759; called by muse, mutect2, varscan2
- WWC3 | c.2285C>T p.A762V | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); catalogued as rs780453778, COSV66505328; called by muse, mutect2, varscan2
- ZIC4 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.511); catalogued as COSV67173343; called by muse, mutect2
- ZNF536 | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs768311266; called by muse, mutect2, varscan2
- ACACA | c.1456A>G p.T486A | Missense Mutation (SNP) | VAF 99/316 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ALDH1L2 | c.1875G>C p.L625F | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- APAF1 | c.2101C>T p.Q701* (on ENST00000551964 / NM_181861.2; = p.Q690* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 61/260 reads (23%) | called by muse, mutect2, varscan2
- ASB8 | c.182G>C p.C61S | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ATP4B | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CABP2 | c.317del p.C106Sfs*34 | Frame Shift Del (DEL) | VAF 50/250 reads (20%) | called by mutect2, pindel, varscan2
- CMYA5 | c.11711G>C p.R3904T | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CTCF | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- CTDSP2 | c.75dup p.K26Qfs*5 | Frame Shift Ins (INS) | VAF 21/87 reads (24%) | called by mutect2, pindel, varscan2
- DIP2B | c.171A>G p.Q57= | Splice Region (SNP) | VAF 36/126 reads (29%) | called by muse, mutect2, varscan2
- EIF3E | c.1300-2A>T p.X434_splice | Splice Site (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- FBXL18 | c.1041C>A p.S347R | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- FOXO6 | c.1375A>G p.M459V | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- KIAA1210 | c.2481C>A p.S827R | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- KMT2B | c.2152G>T p.E718* | Nonsense Mutation (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
- MED16 | c.2246G>T p.R749L | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2
- MGA | c.6421G>T p.E2141* (on ENST00000219905 / NM_001164273.1; = p.E1932* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- MYO15A | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- NALCN | c.4339G>T p.V1447L | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PAPOLG | c.912T>G p.N304K | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PCDH9 | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCNT | c.8837A>G p.E2946G | Missense Mutation (SNP) | VAF 98/398 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PHF8 | c.1240A>G p.I414V (on ENST00000357988 / NM_001184896.1; = p.I378V on NM_015107.3) | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- PIK3R1 | c.1350_1357del p.H450Qfs*12 (on ENST00000521381 / NM_181523.3; = p.H180Qfs*12 on NM_181504.4) | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | called by mutect2, pindel*, varscan2*
- PIK3R1 | c.1651_1653del p.K551del (on ENST00000521381 / NM_181523.3; = p.K281del on NM_181504.4) | In Frame Del (DEL) | VAF 27/123 reads (22%) | called by pindel, varscan2
- PPP2R5D | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 37/394 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2
- SLC23A2 | c.470del p.T157Sfs*26 | Frame Shift Del (DEL) | VAF 31/121 reads (26%) | called by mutect2, pindel, varscan2
- TET2 | c.1930del p.Q644Kfs*56 | Frame Shift Del (DEL) | VAF 62/340 reads (18%) | called by mutect2, pindel, varscan2
- VIPR2 | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ZNF148 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- AARS2 | c.1212C>T p.D404= | Silent (SNP) | VAF 39/545 reads (7%) | catalogued as rs753049833; called by muse, mutect2
- CDC16 | c.996C>G p.T332= | Silent (SNP) | VAF 59/226 reads (26%) | catalogued as rs1054964757; called by muse, mutect2, varscan2
- DRC3 | c.66C>T p.V22= | Silent (SNP) | VAF 54/203 reads (27%) | catalogued as rs754925749; called by muse, mutect2, varscan2
- FAM131A | c.723C>A p.A241= (on ENST00000310585; = p.A272= on NM_144635.5) | Silent (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2, varscan2
- GNL3L | c.1404G>A p.T468= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as rs750039892, COSV60577443; called by muse, mutect2
- HMCN1 | c.9570G>A p.K3190= | Silent (SNP) | VAF 36/309 reads (12%) | catalogued as rs1195586500, COSV99626655; called by muse, mutect2, varscan2
- IFT81 | c.339G>A p.K113= | Silent (SNP) | VAF 35/112 reads (31%) | called by muse, mutect2, varscan2
- ITGA5 | c.1605C>T p.H535= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as rs200698595; called by muse, mutect2, varscan2
- KCNA5 | c.399G>T p.T133= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV99363940; called by muse, mutect2, varscan2
- MBD1 | c.990G>A p.T330= (on ENST00000269468 / NM_001323950.1; = p.T307= on NM_015845.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as rs1377865003, COSV54008951; called by muse, mutect2, varscan2
- MRGPRF | c.804G>A p.P268= | Silent (SNP) | VAF 66/216 reads (31%) | catalogued as rs1422999419, COSV57995554; called by muse, mutect2, varscan2
- MYOCD | c.2013G>A p.G671= | Silent (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- NLRP14 | c.1509T>C p.P503= | Silent (SNP) | VAF 42/468 reads (9%) | called by muse, mutect2
- PAK6 | c.1911G>T p.R637= | Silent (SNP) | VAF 26/136 reads (19%) | called by muse, varscan2
- PLXNA1 | c.2529C>T p.C843= | Silent (SNP) | VAF 114/400 reads (29%) | catalogued as rs768162057; called by muse, mutect2, varscan2
- PSME4 | c.123G>T p.A41= | Silent (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- PTPRM | c.369G>A p.G123= | Silent (SNP) | VAF 52/213 reads (24%) | catalogued as rs1461057681; called by muse, mutect2, varscan2
- RFX6 | c.1761C>T p.D587= | Silent (SNP) | VAF 102/386 reads (26%) | catalogued as rs531536969, COSV60583452; called by muse, mutect2, varscan2
- SBSN | c.1185G>A p.S395= | Silent (SNP) | VAF 42/265 reads (16%) | catalogued as rs750175264, COSV104437991; called by muse, mutect2, varscan2
- SDR9C7 | c.702C>T p.Y234= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs147081896; called by muse, mutect2, varscan2
- SNIP1 | c.75G>A p.A25= | Silent (SNP) | VAF 84/181 reads (46%) | called by muse, mutect2, varscan2
- SSC4D | c.1383G>A p.T461= | Silent (SNP) | VAF 54/452 reads (12%) | catalogued as rs1451319129, COSV99299735; called by muse, mutect2, varscan2
- TELO2 | c.2172C>T p.L724= | Silent (SNP) | VAF 36/171 reads (21%) | catalogued as rs750760448, COSV51979172; called by muse, mutect2, varscan2
- ZXDB | c.306C>T p.G102= | Silent (SNP) | VAF 35/232 reads (15%) | catalogued as COSV100885814; called by muse, mutect2, varscan2
- AC002428.1 | chr5:135922382 C>T | 5'Flank (SNP) | VAF 18/77 reads (23%) | catalogued as rs1300826454; called by muse, mutect2, varscan2
- AC009533.1 | n.1033C>T | RNA (SNP) | VAF 42/652 reads (6%) | catalogued as rs768296382; called by muse, mutect2
- AGPAT2 | c.317-13C>G | Intron (SNP) | VAF 14/170 reads (8%) | catalogued as rs778169961; called by muse, mutect2
- CD4 | c.608-314C>T | Intron (SNP) | VAF 19/246 reads (8%) | catalogued as rs782002864; called by muse, mutect2
- DDX12P | n.981C>T | RNA (SNP) | VAF 14/100 reads (14%) | catalogued as rs1430638041; called by mutect2, varscan2
- DNMT3B | c.-55C>G | 5'UTR (SNP) | VAF 7/68 reads (10%) | catalogued as rs1321509812; called by muse, mutect2, varscan2
- HDAC8 | c.-16C>T | 5'UTR (SNP) | VAF 51/180 reads (28%) | catalogued as COSV65227543; called by muse, mutect2, varscan2
- HS3ST3A1 | c.*1C>G | 3'UTR (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- KLHL3 | c.*33G>T | 3'UTR (SNP) | VAF 42/139 reads (30%) | called by muse, mutect2, varscan2
- LMO7DN | n.272C>T | RNA (SNP) | VAF 46/202 reads (23%) | catalogued as rs953547910, COSV59090457; called by muse, mutect2, varscan2
- MIR421 | n.2C>A | RNA (SNP) | VAF 46/159 reads (29%) | called by muse, mutect2, varscan2
- NLRP3 | c.-23C>A | 5'UTR (SNP) | VAF 59/264 reads (22%) | called by muse, mutect2, varscan2
- PODN | c.90-2934G>T | Intron (SNP) | VAF 47/103 reads (46%) | catalogued as rs1475071908; called by muse, mutect2, varscan2
- RPL26 | c.168+52G>A | Intron (SNP) | VAF 13/101 reads (13%) | catalogued as rs532861404, COSV53447104; called by mutect2, varscan2
- SSPOP | n.14439T>C | RNA (SNP) | VAF 30/250 reads (12%) | called by muse, mutect2, varscan2
